Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TY-01A (Primary Tumor).

Morphology shows oligodendroglial differentiation. Single mitoses present. Proliferation focally up to 6%.

Diagnosis

Oligodendroglioma WHO grade II

ICD-O-3
Oligodendroglioma, grade II
9450/3
Oligodendroglioma NOS
9450/3
Site Brain, supratentorial
C71.0
JW 7/25/13

untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file c39ef5b6-b654-4e92-8fb8-c12a4990fe87 (TCGA-S9-A6TY.13C1027F-56A6-4710-946D-25B496BA6315.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).